Somatic mutation profile of tumor specimen 0DPJT9 from CCDI case PBCDYY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (444 days).
Specimen 0DPJT9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ec27b1b-3e87-4c7b-a229-b5e2c1de7b78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPJSF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcff65ea-cb4a-49ec-8db3-da629d9870aa

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCB1 | c.406C>T p.Q136* (on ENST00000263121; = p.Q182* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 162/221 reads (73%) | catalogued as rs121434496, COSV99575371; ClinVar: pathogenic; called by muse, mutect2
- GANC | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 19/381 reads (5%) | PolyPhen benign (0.097); called by muse, mutect2
- GGN | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 65/332 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LONRF2 | c.1391G>A p.C464Y | Missense Mutation (SNP) | VAF 32/650 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TTC28 | c.1373A>G p.E458G | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- GOPC | c.1374T>C p.H458= | Silent (SNP) | VAF 26/548 reads (5%) | catalogued as rs750852261; called by muse, mutect2
- SAGE1 | c.1797G>A p.S599= | Silent (SNP) | VAF 11/328 reads (3%) | catalogued as rs782161726, COSV61013262; called by muse, mutect2
- CLLU1 | n.897C>T | RNA (SNP) | VAF 46/445 reads (10%) | catalogued as rs369773459, COSV101029275; called by muse, mutect2, varscan2
